RC case RC-B56E — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/377c0016-4cb1-4a1a-91c4-ceed29b3e7bc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1937; Vital status: Alive.

Diagnoses (1)
1. Anaplastic large cell lymphoma, ALK negative: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 77.8 years (28,427 days); Year of diagnosis: 2015; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low Risk; Sites of involvement: Lymph Node, Axillary.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 5.3 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Brentuximab Vedotin + Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: BV-CHOP; Days to treatment start: 32 days; Days to treatment end: 137 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Clinical trial indicator: Yes; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 32 days; Days to treatment end: 137 days; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Day 111 (end of treatment course 1): Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 2,275 days (6.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Lactate Dehydrogenase 208 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Follow-up; Comorbidities: Other Cancer within 5 Years.
- Timepoint category: Initial Diagnosis; Weight: 71.5 kg; Height: 172 cm; BMI: 24.2.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1961; Tobacco smoking quit year: 1986.

Family history
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B56E-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B56E-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B56E-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 83; Percent tumor nuclei: 83; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 2; Percent lymphocyte infiltration: 11; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
